Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A2AE, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A2AE-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Endometrial cancer.

LMP DATE:

Collection Date:

PROCEDURE: Total abdominal hysterectomy with bilateral salpingo-oophorectomy, pelvic lymph node dissection and omentectomy.

SPECIFIC CLINICAL QUESTION: Not listed.

OUTSIDE TISSUE DIAGNOSIS: Not listed.

PRIOR MALIGNANCY: Not listed.

CHEMORADIATION THERAPY: Not listed.

OTHER DISEASES: Not listed.

FINAL DIAGNOSIS:

PART 1: UTERUS, CERVIX (138 GRAMS), OVARIES AND FALLOPIAN TUBES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. **HIGH GRADE ENDOMETRIAL ADENOCARCINOMA (3 CM), MIXED WITH ENDOMETRIOID-TYPE (APPROXIMATELY 80%), PAPILLARY SEROUS-TYPE (5-10%), AND CLEAR CELL-TYPE CARCINOMA (5-10%) (see comment).**
- B. **THE ENDOMETRIOID CARCINOMA COMPONENT IS FIGO GRADE 3, NUCLEAR GRADE 2-3.**
- C. **THE TUMOR INVADERS 95% OF THE MYOMETRIAL THICKNESS (18 MM INVASION OF 18 MM THICK MYOMETRIUM).**
- D. **THE TUMOR INVOLVES APPROXIMATELY 88% OF THE ENDOMETRIAL SURFACE.**
- E. **NO ENDOCERVICAL INVASION IS IDENTIFIED (see comment).**
- F. **LYMPHOVASCULAR SPACE INVASION IS IDENTIFIED (see comment).**
- G. **THE BACKGROUND ENDOMETRIUM IS POLYPOID WITH COMPLEX ATYPICAL HYPERPLASIA AND FOCAL MUCINOUS METAPLASIA.**
- H. **THE UNINVOLVED MYOMETRIUM SHOWS LEIOMYOMATA, INTRAMURAL (LARGEST 1.1 CM) WITH DEGENERATIVE CHANGES.**
- I. **MILD CHRONIC CERVICITIS WITH REACTIVE ENDOCERVICAL EPITHELIUM, ENDOCERVICAL POLYP, FOCAL DYSTROPHIC CALCIFICATION AND NABOTHIAN CYSTS (see comment).**
- J. **UTERINE SEROSAL FIBROUS ADHESIONS.**
- K. **OVARY, LEFT, WITH ENDOMETRIOTIC CYST (3.5 CM), SURFACE EPITHELIAL INCLUSIONS CYSTS, AND PHYSIOLOGIC CHANGES.**
- L. **OVARY, RIGHT, WITH SURFACE EPITHELIAL INCLUSION CYSTS AND PHYSIOLOGIC CHANGES.**
- M. **FALLOPIAN TUBES, BILATERAL, WITH REACTIVE EPITHELIAL CHANGES AND OTHERWISE UNREMARKABLE.**

PART 2: LYMPH NODES, LEFT PELVIC, EXCISION -
FOUR LYMPH NODES, NEGATIVE FOR CARCINOMA (0/4).

PART 3: LYMPH NODES, RIGHT PELVIC, EXCISION -
A. **FEW METASTATIC TUMOR CELLS INVOLVING ONE OF FOUR LYMPH NODES (1/4) (see comment).**
B. **NO EXTRACAPSULAR EXTENSION PRESENT.**

PART 4: OMENTUM, PARTIAL EXCISION -
OMENTAL ADIPOSE TISSUE, NEGATIVE FOR CARCINOMA.

COMMENT:

Part 1: The patient's prior endometrial biopsy results showing high grade endometrial adenocarcinoma (see comment) are noted. Multiple sections of the tumor were reviewed and ancillary immunohistochemical stains were performed (see microscopic description for further details). The tumor has a mixed histomorphology and immunophenotypic appearance. The tumor is composed predominantly of an endometrioid type adenocarcinoma with a minor solid architectural component and grade 2-3 nuclear features. The tumor also displays foci with papillary features, high grade nuclei, and scattered psammoma bodies consistent with serous carcinoma (comprising 5-10% of the tumor). Additional tumor foci display papillary features with cytoplasmic clearing, variably high grade nuclei, focal hyalinized stroma and hyaline globules consistent with clear cell carcinoma (comprising 5-10% of the tumor). Dr. [redacted] has reviewed selected slides of the tumor and agrees with the interpretation.

The entire cervix was submitted for histologic evaluation; the ectocervical squamous mucosa is not identified.

Part 3: Few tumor cells with positive expression for cytokeratin AE1/AE3 are identified involving one lymph node, and involving lymphatic spaces located at the lymph node capsule (see microscopic description for further details). The largest metastatic focus consists of less than 20 tumor cells. Dr. [redacted] has reviewed part 3 of this case and agrees with the interpretation.

Office was contacted.

Please also see concurrent pelvic wash specimen results.

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL CARCINOMA & CARCINOSARCOMA : HYSTERECTOMY

TUMOR TYPE:	SPECIMENS:	
HISTOLOGIC GRADE (epithelial neoplasm):	Mixed carcinoma, Serous: 10%, Endometrioid: 80%, Clear cell: 10%	
	(combined architectural and nuclear):	
ARCHITECTURAL GRADE:	Poorly differentiated (FIGO 3)	
NUCLEAR GRADE:	Moderately differentiated	
TUMOR SIZE:	Grade 3	
PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:	Maximum dimension: 30 mm	
DEPTH OF INVASION:	Anterior endomyometrium: 60 %, Posterior endomyometrium: 80 %	
ANGIOLYMPHATIC INVASION:	Greater than or equal to 1/2 thickness of myometrium	
PRE-NEOPLASTIC CONDITIONS:	Yes	
OTHER:	Complex endometrial hyperplasia with atypia	
MITOTIC RATE:	Endometrial polyp, Leiomyoma, Others Endocervical polyp	
LYMPH NODES POSITIVE:	Mitotic rate: 17 / 10 HPF	
LYMPH NODES EXAMINED:	Number of lymph nodes positive: 1	
LYMPH NODE GROUPS INVOLVED:	Total number of lymph nodes examined: 6	
T STAGE, PATHOLOGIC:	Pelvic lymph nodes, Right	
N STAGE, PATHOLOGIC:	pT1b	
M STAGE, PATHOLOGIC:	pN1	
FIGO STAGE:	Not applicable	
	IIIC1	

Per email documentation -
case has < 10% clear cell.
lw

Criteria	less than	Yes	No
Diagnosis Discrepancy	clear cell 10%		
IIIC1 Discrepancy			
Quality/Chronology Primary Listed			
	5/26/11		

1CD-0-3

Carcinoma, endometrioid, serous, clear cell Mixed

(code to highest) - serous 8441/3

Site: Endometrium C54.1

5/26/11 lw

Source: NCI Genomic Data Commons file 029c9f86-1ce4-43ea-a986-50c91a7481a9 (TCGA-BG-A2AE.BA5BC88E-6A6C-425E-84B4-EC33DB9AC146.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).